Gene-level copy-number profile of tumor specimen TCGA-D7-6815-01A from TCGA case TCGA-D7-6815, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.7 years (25,811 days).
Specimen TCGA-D7-6815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d94304ec-ca81-49e6-aad3-dae00b1bf5bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6815-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c44fc47a-9226-42a7-ba2e-eeb7e40ca818

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 13,246; copy number 2: 40,334; copy number 3: 4,417; copy number 4: 1,479; copy number 6: 21; copy number 7: 21; copy number 11: 45; copy number 14: 204.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6815-01A-11D-1881-01): tumor purity 0.82, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,178,589–22,214,672, 47 genes: IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 291 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:28,259,297–28,528,215, 16 genes, copy number 6 (within-gene range 3–6): NKAPL, ZSCAN26, AL021997.2, PGBD1, AL021997.1, SMIM15P2, ZSCAN31, ZKSCAN3, ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, Z98745.2, Z98745.1, GPX6.
- chr6:41,026,895–41,350,889, 21 genes, copy number 7 (within-gene range 3–7): UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2.
- chr7:108,720,608–108,995,029, 5 genes, copy number 6: AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr17:36,936,785–41,836,260, 249 genes, copy number 11–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
